Gene-level copy-number profile of tumor specimen TCGA-CV-A464-01A from TCGA case TCGA-CV-A464, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 48.4 years (17,669 days).
Specimen TCGA-CV-A464-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.5cc941e9-67b0-4e35-b671-3a448936cb85.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-A464-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/15c80500-aa2b-4147-8213-940937954023

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 8,758; copy number 2: 45,999; copy number 3: 2,632; copy number 4: 1,032; copy number 5: 668; copy number 6: 528; copy number 7: 46; copy number 8: 69; copy number 10: 10; copy number 14: 13; copy number 20: 31.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-A464-01A-11D-A25X-01): tumor purity 0.28, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,365 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–51,015,165, 77 genes, copy number 5 (broad region; genes not listed).
- chr8:105,546,089–145,066,685, 584 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr9:104,927,553–109,119,947, 60 genes, copy number 5–20: AL359182.1, CT70, AL591506.1, RN7SKP191, SLC44A1, FSD1L, RALGAPA1P1, AL158070.1, FKTN, AL158070.2, TAL2, TMEM38B, AL592437.1, DEPDC1P2, SLC25A6P5, LINC01505, AL732323.1, AL451140.1, MIR8081, AL512649.2, RN7SKP77, AL512649.1, RNA5SP292, ZNF462, AL807761.4, AL512593.1, AL807761.1, AL807761.2, AL807761.3, AL445487.1, RAD23B, LINC01509, AL359552.1, HMGN2P32, RNU6-492P, KLF4, AL389915.1, PPIAP88, RNU6-996P, RNU6-1064P, RN7SL659P, RPL36AP6, AL162389.1, RNA5SP293, RPS15AP27, AC068050.1, CHCHD4P2, AL353742.1, AL669983.1, AL358779.1, RPL36AP35, AL359692.1, ACTL7B, ACTL7A, ELP1, ABITRAM, CTNNAL1, TMEM245, Y_RNA, MIR32.
- chr14:22,052,514–22,509,406, 69 genes, copy number 8 (broad region; genes not listed).
- chr14:33,677,360–64,546,173, 528 genes, copy number 6 (broad region; genes not listed).
- chr18:25,818,234–29,650,440, 47 genes, copy number 7–14: RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1, AC117569.1, AC117569.2.

Autosomal genes at a single copy (total copy number 1): 6,403. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
